Somatic mutation profile of tumor specimen TCGA-LN-A49P-01A (aliquot TCGA-LN-A49P-01A-11D-A247-09) from TCGA case TCGA-LN-A49P, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 71.7 years (26,189 days).
Specimen TCGA-LN-A49P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e5c3964e-2a9b-4a52-9e47-227e5d1bddd7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LN-A49P-10A (Blood Derived Normal), aliquot TCGA-LN-A49P-10A-01D-A247-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a1d2e1b1-db2d-446a-8593-27e61bcc48d8

The open-access MAF lists 77 somatic variants for this specimen: 58 protein-altering or splice-affecting, 16 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 16, Nonsense Mutation 5, Frame Shift Del 3, Splice Site 2, 3'UTR 1, Frame Shift Ins 1, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TGFBR2 | c.1336G>A p.D446N | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs886039551, CM060085, CM086981, COSV55445539, COSV55457221; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.673-2A>G p.X225_splice | Splice Site (SNP) | VAF 48/103 reads (47%) | hotspot (GDC flag); catalogued as rs1555525585, CS109519, COSV52669186, COSV52682653, COSV52687702; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2, varscan2
- AHNAK | c.1366C>T p.P456S | Missense Mutation (SNP) | VAF 24/35 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1207184560; called by muse, mutect2, varscan2
- ARMCX5 | c.1299T>G p.Y433* | Nonsense Mutation (SNP) | VAF 72/114 reads (63%) | catalogued as COSV55766344; called by muse, mutect2, varscan2
- DNAH7 | c.7220C>G p.S2407C | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs1452637611, COSV56762334; called by muse, mutect2, varscan2
- ENOX1 | c.85G>A p.G29R | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated, low confidence (0.93); PolyPhen possibly damaging (0.796); catalogued as rs1253617704; called by muse, mutect2, varscan2
- EP300 | c.4199G>T p.S1400I | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54344894; called by muse, mutect2, varscan2
- FAM9A | c.831+1G>T p.X277_splice | Splice Site (SNP) | VAF 23/55 reads (42%) | catalogued as COSV101121371; called by muse, mutect2, varscan2
- FIGN | c.2050C>T p.R684C | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs747101469, COSV60769588; called by muse, mutect2, varscan2
- FNDC1 | c.5623G>A p.G1875R | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT tolerated (0.36); PolyPhen benign (0.336); catalogued as rs1219737934, COSV51939510; called by muse, mutect2, varscan2
- GINS4 | c.169C>T p.Q57* | Nonsense Mutation (SNP) | VAF 16/83 reads (19%) | catalogued as rs1270004502; called by muse, mutect2, varscan2
- GPR32 | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.782); catalogued as rs756541448, COSV54514878; called by muse, mutect2, varscan2
- GRM8 | c.1598del p.P533Lfs*32 | Frame Shift Del (DEL) | VAF 21/155 reads (14%) | catalogued as COSV58841024; called by mutect2, pindel, varscan2
- KCNA1 | c.176C>G p.P59R | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101230328; called by muse, mutect2, varscan2
- LAMA2 | c.3985T>C p.F1329L | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV70355804; called by muse, mutect2
- PELI2 | c.170G>T p.S57I | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.857); catalogued as rs1262171032; called by muse, mutect2, varscan2
- TF | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV53921547; called by muse, mutect2, varscan2
- TOR1AIP2 | c.863C>T p.S288F | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62626556; called by muse, mutect2, varscan2
- TRIB3 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs1308182353, COSV99423743; called by muse, mutect2, varscan2
- UNC13B | c.3205G>A p.V1069M | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs140663072; called by muse, mutect2, varscan2
- VWF | c.7966G>A p.G2656R | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1043399177; called by muse, mutect2
- WNT9A | c.566A>G p.K189R | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as rs894757369; called by muse, mutect2, varscan2
- ZNF479 | c.1304G>A p.R435K | Missense Mutation (SNP) | VAF 4/101 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs782119299, COSV58637632; called by muse, mutect2
- ASXL1 | c.1735A>T p.I579F | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAD | c.753C>G p.I251M | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- CENPF | c.775T>G p.L259V | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- CSMD3 | c.10027C>T p.H3343Y (on ENST00000297405 / NM_001363185.1; = p.H3174Y on NM_052900.3) | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- CTNNA3 | c.2408G>A p.S803N | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- DGKI | c.2174G>C p.R725T | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- DIPK1B | c.1254G>T p.K418N | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- DMTF1 | c.1065_1068del p.D355Efs*12 | Frame Shift Del (DEL) | VAF 45/151 reads (30%) | called by mutect2, pindel, varscan2
- DOCK2 | c.5274G>A p.M1758I | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GAL3ST2 | c.595T>A p.F199I | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- KIRREL1 | c.1808A>G p.N603S | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- KIRREL3 | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LPCAT3 | c.1237A>G p.I413V | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRPPRC | c.3529A>G p.M1177V | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- MAP3K1 | c.3883del p.I1295* | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | called by mutect2, pindel, varscan2
- MSTO1 | c.1386G>C p.M462I | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC5B | c.13559C>A p.T4520N | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- MXI1 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NBN | c.246A>T p.K82N | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NKPD1 | c.1631C>T p.A544V | Missense Mutation (SNP) | VAF 77/131 reads (59%) | SIFT tolerated (0.58); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- NXF3 | c.5C>A p.S2* | Nonsense Mutation (SNP) | VAF 53/83 reads (64%) | called by muse, mutect2, varscan2
- PARM1 | c.202G>A p.V68I | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PCSK9 | c.415C>T p.H139Y | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- PIKFYVE | c.3995C>T p.S1332F | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PKD1L1 | c.7567C>T p.L2523F | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- RANBP2 | c.4166C>T p.P1389L | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.299); called by muse, mutect2
- SLC16A4 | c.928C>G p.L310V | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- SLC26A7 | c.332C>T p.S111L | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLITRK2 | c.1282C>A p.L428I | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TCHH | c.3854G>A p.R1285H | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- THBS4 | c.2720_2729dup p.T911Lfs*35 | Frame Shift Ins (INS) | VAF 24/66 reads (36%) | called by mutect2, varscan2
- TIMM44 | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 21/101 reads (21%) | called by muse, mutect2, varscan2
- UBR7 | c.283A>T p.R95* | Nonsense Mutation (SNP) | VAF 24/97 reads (25%) | called by muse, mutect2, varscan2
- VMP1 | c.869G>A p.G290D | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF441 | c.1210T>G p.Y404D | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- ARID1B | c.2652A>T p.G884= | Silent (SNP) | VAF 23/77 reads (30%) | called by muse, mutect2, varscan2
- CDC27 | c.459A>G p.E153= | Silent (SNP) | VAF 9/41 reads (22%) | called by muse, mutect2, varscan2
- FAM13A | c.705T>C p.Y235= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV52014230; called by muse, mutect2, varscan2
- GAPVD1 | c.1665C>T p.L555= | Silent (SNP) | VAF 24/107 reads (22%) | called by muse, mutect2, varscan2
- JADE2 | c.342C>T p.A114= | Silent (SNP) | VAF 13/94 reads (14%) | called by muse, mutect2, varscan2
- LMO7 | c.2838G>A p.P946= (on ENST00000357063; = p.P627= on NM_005358.5) | Silent (SNP) | VAF 19/96 reads (20%) | catalogued as rs978302301, COSV58532969, COSV58542348; called by muse, mutect2, varscan2
- MAP9 | c.1467C>A p.A489= | Silent (SNP) | VAF 4/64 reads (6%) | called by muse, mutect2
- MDGA2 | c.2742A>G p.G914= (on ENST00000399232 / NM_001113498.2; = p.G616= on NM_182830.4) | Silent (SNP) | VAF 17/94 reads (18%) | called by muse, mutect2, varscan2
- MMP28 | c.1065C>T p.N355= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as rs376963669; called by muse, mutect2
- MSI1 | c.831G>A p.A277= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs561139090; called by muse, mutect2, varscan2
- PEX5L | c.675C>T p.S225= | Silent (SNP) | VAF 15/96 reads (16%) | catalogued as rs139208096, COSV99828654; called by muse, mutect2, varscan2
- PID1 | c.456G>A p.G152= (on ENST00000354069 / NM_001330156.1; = p.G150= on NM_017933.5) | Silent (SNP) | VAF 21/146 reads (14%) | called by muse, mutect2, varscan2
- PRDM14 | c.1500C>T p.A500= | Silent (SNP) | VAF 35/149 reads (23%) | called by muse, mutect2, varscan2
- SYNPO | c.2154C>T p.S718= (on ENST00000394243 / NM_001166208.2; = p.S474= on NM_007286.6) | Silent (SNP) | VAF 19/32 reads (59%) | catalogued as rs761150754, COSV100302465; called by muse, mutect2, varscan2
- TMCC1 | c.1635C>G p.A545= (on ENST00000393238 / NM_001349268.2; = p.A221= on NM_015008.5 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 17/62 reads (27%) | called by muse, mutect2, varscan2
- TTLL13P | c.972C>T p.H324= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as rs1349869948; called by muse, mutect2, varscan2
- CEP295 | chr11:93730589 G>C | 3'Flank (SNP) | VAF 15/69 reads (22%) | catalogued as rs748406822; called by muse, mutect2, varscan2
- SLC3A2 | chr11:62855326 A>G | 5'Flank (SNP) | VAF 9/42 reads (21%) | called by muse, mutect2, varscan2
- XIRP2 | c.*1363G>C | 3'UTR (SNP) | VAF 17/101 reads (17%) | called by muse, mutect2, varscan2
